Gene-level copy-number profile of specimen HCM-BROD-0002-C71-85A from HCMI case HCM-BROD-0002-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Gliosarcoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.3 years (24,213 days).
Specimen HCM-BROD-0002-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fc459a70-d2d2-45a8-98e0-be4583e8182a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0002-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/f8d66572-d63f-44c6-831b-1b1e0afbc2f0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 10,509; copy number 2: 44,730; copy number 3: 798; copy number 4: 2,753; copy number 5: 105.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:65,386,621–65,538,704, 16 genes (within-gene range 0–2): FRMD8, NEAT1, AP000944.4, AP000944.3, AP000944.2, MIR612, AP000769.4, AP000769.1, LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3, SNRPGP19, SCYL1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 105 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:8,262,233–8,752,961, 4 genes, copy number 5 (within-gene range 4–5): AC007009.1, AC007128.1, AC007128.2, NXPH1.
- chr7:31,119,284–31,708,455, 6 genes, copy number 5: AC006466.1, AC006380.1, NEUROD6, AC005090.1, ITPRID1, PPP1R17.
- chr7:47,275,154–54,812,727, 77 genes, copy number 5 (broad region; genes not listed).
- chr7:152,590,641–154,894,285, 18 genes, copy number 5: AC104843.2, 5S_rRNA, AC104843.1, AC003109.1, XRCC2, ATP5PBP3, RN7SL845P, ACTR3B, AC079809.1, LINC01287, PAXBP1P1, DPP6, AC005588.1, AC006019.3, AC006019.1, AC006019.2, AC024730.1, AC073336.1.

Autosomal genes at a single copy (total copy number 1): 7,653. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
